Somatic mutation profile of cancer-model specimen HCM-CSHL-0467-C56-85M (3D Organoid, passage 2; aliquot HCM-CSHL-0467-C56-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0467-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage III; Tumor grade: High Grade.
Specimen HCM-CSHL-0467-C56-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70836f85-d9d6-411a-b301-872a0a2a874e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0467-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0467-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/624676c1-3c26-45e7-bb22-deef8bd0093a

The open-access MAF lists 99 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 6, 3'Flank 1, 5'UTR 1, In Frame Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 263/268 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.183); catalogued as rs921364290, COSV100530299; called by muse, mutect2, varscan2
- ANKRD31 | c.4066G>T p.D1356Y | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57156524; called by muse, mutect2, varscan2
- BRSK1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 172/595 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs777359528; called by muse, mutect2, varscan2
- CDKN2A | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 314/656 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1190283873, CM097979; called by muse, mutect2, varscan2
- CPZ | c.1849G>A p.D617N (on ENST00000360986 / NM_001014447.3; = p.D606N on NM_003652.3) | Missense Mutation (SNP) | VAF 209/475 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs760245531, COSV59923902; called by muse, mutect2, varscan2
- DNAH1 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 187/866 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs374856706; called by muse, mutect2, varscan2
- EPS8L3 | c.1729C>T p.R577* (on ENST00000361965 / NM_133181.4; = p.R547* on NM_024526.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 192/588 reads (33%) | catalogued as rs147585592; called by muse, mutect2, varscan2
- FUT9 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 109/476 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.02); catalogued as rs1412403248; called by muse, mutect2, varscan2
- HK2 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 254/545 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs760432076; called by muse, mutect2, varscan2
- HYPK | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 127/455 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202106711, COSV51038302; called by muse, mutect2, varscan2
- ICAM4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53425967; called by muse, mutect2, varscan2
- IER5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 274/826 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1445529006; called by muse, varscan2
- INO80D | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766341670; called by muse, mutect2, varscan2
- KCTD11 | c.263G>A p.R88H (on ENST00000333751 / NM_001363642.1; = p.R49H on NM_001002914.2) | Missense Mutation (SNP) | VAF 225/521 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50135132; called by muse, mutect2, varscan2
- LRP2 | c.9127C>T p.R3043C | Missense Mutation (SNP) | VAF 507/515 reads (98%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs760320712, COSV55560197; called by muse, mutect2, varscan2
- LRP2 | c.5668C>A p.Q1890K | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as COSV99790173; called by muse, mutect2, varscan2
- LRP2 | c.4765C>T p.R1589C | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879176581, COSV55567293; called by muse, mutect2
- MYH7B | c.3464A>T p.K1155M | Missense Mutation (SNP) | VAF 135/662 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs201622278; called by muse, mutect2, varscan2
- OLFM1 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs1372384625; called by muse, mutect2, varscan2
- PCDHB15 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 97/474 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV50858314; called by muse, mutect2, varscan2
- PCYT1A | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 116/582 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs867290911, COSV53057919; called by muse, mutect2, varscan2
- PNMA8A | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 197/540 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58138430; called by muse, mutect2, varscan2
- PNPLA6 | c.2773C>T p.R925C (on ENST00000414982 / NM_001166111.2; = p.R877C on NM_006702.5) | Missense Mutation (SNP) | VAF 304/562 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377171140; called by muse, mutect2, varscan2
- RCHY1 | c.195_196del p.C65* | Nonsense Mutation (DEL) | VAF 63/195 reads (32%) | catalogued as rs778879251; called by pindel, varscan2
- RELCH | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56881987; called by muse, mutect2, varscan2
- RNF139 | c.1760A>T p.Q587L | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV104372530; called by muse, mutect2, varscan2
- RTL1 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 229/735 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs747974765; called by muse, mutect2, varscan2
- SEMA3D | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1562816970, COSV52388637; called by muse, mutect2, varscan2
- SLC46A3 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 81/177 reads (46%) | catalogued as rs768643720, COSV57180202; called by muse, mutect2, varscan2
- SLC8B1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 208/714 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs538747610, COSV99176662; called by muse, mutect2, varscan2
- SNX7 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1431330339, COSV60269239; called by muse, mutect2, varscan2
- TAX1BP3 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 136/304 reads (45%) | catalogued as rs749730290; called by muse, mutect2, varscan2
- TIMM44 | c.427C>G p.R143G | Missense Mutation (SNP) | VAF 184/384 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV54493528, COSV99564009; called by muse, mutect2, varscan2
- ZIC5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 493/776 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs913816048; called by muse, mutect2, varscan2
- ACBD3 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD37 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 162/354 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.2249C>G p.P750R | Missense Mutation (SNP) | VAF 155/318 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AURKA | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 805/1245 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D2 | c.3129C>A p.H1043Q (on ENST00000479441 / NM_001174051.3; = p.H1036Q on NM_006030.4) | Missense Mutation (SNP) | VAF 109/490 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH26 | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 139/949 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMBL | c.272G>C p.W91S | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CPT1B | c.442T>G p.L148V | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP46A1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- DEAF1 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 131/401 reads (33%) | called by muse, mutect2, varscan2
- DTX1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 146/487 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ECHDC1 | c.643G>A p.A215T (on ENST00000531967 / NM_001139510.1; = p.A209T on NM_001002030.2) | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ELOVL4 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 175/399 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0895L | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LINGO2 | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LRRC24 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAF | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MAP3K6 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 248/846 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEPCE | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 344/1060 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); called by muse, varscan2
- METTL11B | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.3699T>G p.S1233R | Missense Mutation (SNP) | VAF 136/462 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MYO5A | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 150/470 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR51A4 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 10/425 reads (2%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OTOGL | c.1292T>C p.V431A (on ENST00000547103; = p.V422A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PAGR1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 215/712 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRR27 | c.17G>C p.W6S | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2C | c.8320G>C p.E2774Q (on ENST00000367742; = p.E2772Q on NM_015172.4) | Missense Mutation (SNP) | VAF 138/457 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PRX | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 127/844 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PSMC2 | c.818T>G p.F273C | Missense Mutation (SNP) | VAF 152/261 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM39 | c.1508C>G p.A503G (on ENST00000253363 / NM_001323424.2; = p.A497G on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RSRC1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCIN | c.1301G>A p.G434E (on ENST00000297029 / NM_001112706.3; = p.G187E on NM_033128.3) | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SHH | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 201/824 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SLC25A38 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 117/534 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMED6 | c.538_559del p.Y180Kfs*15 | Frame Shift Del (DEL) | VAF 76/239 reads (32%) | called by mutect2, pindel, varscan2
- TXK | c.585_587dup p.T196dup | In Frame Ins (INS) | VAF 77/178 reads (43%) | called by mutect2, pindel, varscan2
- WWC1 | c.2768C>A p.T923N | Missense Mutation (SNP) | VAF 154/824 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XPO1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 84/682 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ANKRD36C | c.201C>T p.T67= | Silent (SNP) | VAF 23/187 reads (12%) | catalogued as rs942548316; called by muse, mutect2, varscan2
- CRHR1 | c.90C>T p.C30= | Silent (SNP) | VAF 154/644 reads (24%) | catalogued as rs543785844, COSV53278342; called by muse, mutect2, varscan2
- EIF1 | c.135T>A p.T45= | Silent (SNP) | VAF 6/542 reads (1%) | catalogued as COSV60422169; called by muse*, mutect2
- FAAH | c.1137G>A p.G379= | Silent (SNP) | VAF 107/380 reads (28%) | called by muse, mutect2, varscan2
- FAM234B | c.618T>G p.A206= | Silent (SNP) | VAF 62/469 reads (13%) | called by muse, mutect2, varscan2
- FBXO45 | c.105C>T p.A35= | Silent (SNP) | VAF 155/614 reads (25%) | called by muse, mutect2, varscan2
- FNDC1 | c.1263G>C p.L421= | Silent (SNP) | VAF 136/594 reads (23%) | called by muse, mutect2, varscan2
- FPGT | c.1374T>A p.A458= | Silent (SNP) | VAF 96/346 reads (28%) | called by muse, mutect2, varscan2
- HNF4G | c.804C>T p.I268= (on ENST00000354370 / NM_001330561.2; = p.I315= on NM_004133.5) | Silent (SNP) | VAF 107/384 reads (28%) | catalogued as rs748968405, COSV62966170, COSV62973661; called by muse, mutect2, varscan2
- KCNH7 | c.2010C>T p.Y670= | Silent (SNP) | VAF 126/356 reads (35%) | catalogued as rs891069994, COSV59789745; called by muse, mutect2, varscan2
- MED15 | c.2145C>T p.L715= (on ENST00000263205 / NM_001003891.3; = p.L675= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 289/296 reads (98%) | called by muse, mutect2
- NUF2 | c.1164T>C p.Y388= | Silent (SNP) | VAF 74/236 reads (31%) | called by mutect2, varscan2
- OGFOD3 | c.717C>T p.F239= | Silent (SNP) | VAF 211/348 reads (61%) | catalogued as rs950740124; called by muse, mutect2, varscan2
- OR10J5 | c.252C>T p.S84= | Silent (SNP) | VAF 94/344 reads (27%) | catalogued as rs897293838, COSV100604864; called by muse, mutect2, varscan2
- PHF21A | c.492T>C p.S164= | Silent (SNP) | VAF 12/424 reads (3%) | catalogued as COSV57648944; called by muse, mutect2
- PKN1 | c.120G>A p.E40= | Silent (SNP) | VAF 223/1443 reads (15%) | called by muse, mutect2, varscan2
- PLBD1 | c.111T>C p.P37= | Silent (SNP) | VAF 174/430 reads (40%) | called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SHANK1 | c.4089G>C p.A1363= | Silent (SNP) | VAF 17/613 reads (3%) | called by muse, mutect2
- SLC28A1 | c.600C>T p.C200= | Silent (SNP) | VAF 134/368 reads (36%) | catalogued as rs771748099, COSV99722339; called by muse, mutect2, varscan2
- SPIN1 | c.675C>A p.G225= | Silent (SNP) | VAF 56/360 reads (16%) | called by mutect2, varscan2
- ZNF467 | c.564C>T p.C188= | Silent (SNP) | VAF 52/1150 reads (5%) | called by muse, mutect2
- ZNF544 | c.699C>T p.N233= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as rs769187951; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+24759A>C | Intron (SNP) | VAF 209/338 reads (62%) | called by muse, mutect2, varscan2
- RGS8 | c.-134A>T | 5'UTR (SNP) | VAF 128/486 reads (26%) | called by muse, mutect2, varscan2
- SLC44A5 | chr1:75203740 G>C | 3'Flank (SNP) | VAF 70/272 reads (26%) | called by muse, mutect2, varscan2
